Gene-level copy-number profile of tumor specimen TCGA-H4-A2HQ-01A from TCGA case TCGA-H4-A2HQ, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 64.4 years (23,538 days).
Specimen TCGA-H4-A2HQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.8c257832-d5cc-4670-b167-407c4545a5e5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-H4-A2HQ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2db4dadf-b86c-4a4c-b009-7d99a5d93b38

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 17; copy number 1: 84; copy number 2: 3,798; copy number 3: 12,271; copy number 4: 11,820; copy number 5: 9,803; copy number 6: 11,366; copy number 7: 6,241; copy number 8: 1,608; copy number 9: 2,181; copy number 10: 3; copy number 11: 47; copy number 12: 28; copy number 13: 51; copy number 14: 121; copy number 15: 97; copy number 17: 124; copy number 21: 30; copy number 27: 101; copy number 28: 22.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-H4-A2HQ-01A-11D-A17S-01): tumor purity 0.8, ploidy 4.57, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:9,799,423–9,803,784, 1 gene: AL513422.1.
- chr9:21,695,176–22,128,103, 16 genes: KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 10,654 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:60,515,716–83,480,024, 315 genes, copy number 7–14 (broad region; genes not listed).
- chr1:115,700,021–121,580,524, 136 genes, copy number 7 (broad region; genes not listed).
- chr1:158,560,606–161,524,013, 142 genes, copy number 7–15 (within-gene range 4–15) (broad region; genes not listed).
- chr1:168,178,962–175,922,145, 166 genes, copy number 14–27 (within-gene range 4–27) (broad region; genes not listed).
- chr1:175,968,398–176,018,760, 2 genes, copy number 14: SCARNA3, AL590723.1.
- chr2:38,814–14,992,066, 228 genes, copy number 8 (within-gene range 6–8) (broad region; genes not listed).
- chr2:142,131,178–142,543,975, 2 genes, copy number 7: AC078882.1, UBE2V1P14.
- chr3:84,958,989–86,496,996, 10 genes, copy number 8–10 (within-gene range 3–10): CADM2, MIR5688, CADM2-AS2, CADM2-AS1, THAP12P2, AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070.
- chr3:90,184,634–117,139,389, 317 genes, copy number 7 (within-gene range 1–7) (broad region; genes not listed).
- chr3:117,544,205–198,222,513, 1,478 genes, copy number 7 (broad region; genes not listed).
- chr5:2,712,591–45,895,970, 631 genes, copy number 9 (broad region; genes not listed).
- chr5:52,579,555–52,799,956, 2 genes, copy number 10 (within-gene range 3–10): MFSD4BP1, AC022126.1.
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 7–9 (broad region; genes not listed).
- chr11:69,425,690–75,243,704, 208 genes, copy number 8–13 (broad region; genes not listed).
- chr11:75,260,127–75,265,170, 3 genes, copy number 8: AP001972.1, AP001972.5, AP001972.2.
- chr12:58,544,124–60,419,293, 22 genes, copy number 28: AC020637.1, LINC02388, LRIG3, AC068305.2, RPS6P22, AC068305.1, AC046129.1, AC108721.2, AC108721.1, RNU6-279P, RNU6-871P, LINC02448, RNU4-20P, SLC16A7, AC079905.2, AC079905.1, AC080011.1, AC087883.2, AC087883.1, Y_RNA, AC090022.1, AC090022.2.
- chr12:65,466,820–74,402,600, 154 genes, copy number 17–21 (within-gene range 5–21) (broad region; genes not listed).
- chr14:18,333,726–21,830,070, 214 genes, copy number 7 (broad region; genes not listed).
- chr14:32,879,246–34,630,160, 17 genes, copy number 7 (within-gene range 4–7): AL049781.1, NPAS3, AL161851.1, AL161851.2, EGLN3, EGLN3-AS1, AL356806.1, SPTSSA, RPL23AP71, EAPP, AL445363.3, AL445363.1, RNU1-27P, RNU1-28P, AL445363.2, SNX6, RPS19P3.
- chr17:40,553,769–83,095,122, 1,511 genes, copy number 7 (broad region; genes not listed).
- chr19:27,638,483–58,605,223, 1,686 genes, copy number 7 (broad region; genes not listed).
- chr20:87,250–64,313,132, 1,458 genes, copy number 8–9 (broad region; genes not listed).
- chr21:10,328,411–36,004,667, 418 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 75. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
